Gene-level copy-number profile of tumor specimen RC-B658-TBP1-A from RC case RC-B658, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Anaplastic large cell lymphoma, ALK negative; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 53.5 years (19,550 days).
Specimen RC-B658-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0aa5c328-96cd-4a9e-a53a-8447c8468a5c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B658-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/f8bf464d-4b7c-4f63-afe4-b1c4d2b0c809

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 4,702; copy number 2: 46,189; copy number 3: 7,343; copy number 4: 79; copy number 5: 49.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:191,823,432–192,185,815, 3 genes: LINC02770, AL359081.1, RGS18.
- chr1:192,246,708–192,247,947, 2 genes: AL513175.1, AL513175.2.
- chr9:21,304,326–21,559,900, 18 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 49 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:8,224,815–9,892,099, 49 genes, copy number 5: CTC1, PFAS, AC135178.6, SLC25A35, RANGRF, AC135178.7, ARHGEF15, AC135178.2, AC135178.1, AC135178.5, ODF4, KRBA2, AC135178.4, AC135178.3, RPL26, RNF222, NDEL1, MYH10, RNU7-43P, PPIAP52, AC025518.1, CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3, STX8, AC005695.2, AC087501.1, AC087501.2, AC087501.3, AC087501.4, CFAP52, RPL19P18, AC118755.2, USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45.

Autosomal genes at a single copy (total copy number 1): 2,358. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
